TCGA case TCGA-36-2534 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: BC Cancer Agency. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e08a619d-8a55-435d-8c41-a77a112ed889

Demographics
Sex at birth: female; Race: white; Age at index: 72 years; Vital status: Alive.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 72.9 years (26,621 days); Year of diagnosis: 2007; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No; Residual disease: R1; Days to last follow up: 907 days (2.5 years).
   Pathology details: Residual tumor measurement: >20 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 27 days; Days to treatment end: 154 days; Number of cycles: 7; Treatment dose: 3,735 mg; Prescribed dose: 470; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Treatment intent type: Adjuvant; Days to treatment start: 27 days; Days to treatment end: 154 days; Number of cycles: 7; Treatment dose: 949 mg; Prescribed dose: 135; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 544 days (1.5 years); Days to treatment end: 685 days (1.9 years); Number of cycles: 6; Treatment dose: 3,720 mg; Prescribed dose: 600; Prescribed dose units: mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Progression of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 73.9 years (27,004 days); Days to diagnosis: 383 days (1.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (3 entries)
- Day 383 (post initial treatment): Progression or recurrence: Yes; Days to progression: 383 days (1.0 years); Evidence of progression type: Convincing Image Source.
- Days to follow up: 907 days (2.5 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Prior to Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-36-2534-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 0.9; Shortest dimension: 0.5.
  Slide TCGA-36-2534-01A-01-BS1: Section location: Bottom; Percent tumor cells: 89; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 8.
  Slide TCGA-36-2534-01A-01-TS1: Section location: Top; Percent tumor cells: 83; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 15.
- Sample TCGA-36-2534-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Pre-Adjuvant Therapy; Anatomic organ subdivision: Right; Method initial path diagnosis: Tumor resection.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Follow-up form: Treatment outcome first course: Partial Remission/Response; Tumor status: With tumor; Performance status timing: Pre-Adjuvant Therapy.

GDC annotations on this case (curator notes; quoted as recorded):
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-36-2534-01A-01R-1048-01: Pairwise comparisons of expression results between platforms HT_HG-U133A and AgilentG4502A_07 suggests that results from this aliquot were from a different patient and therefore these data have been removed.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 907 days; disease-specific survival: no event (censored), 907 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 383 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-36-2534-01A-01D-1043-01): tumor purity 0.91, ploidy 1.94, whole-genome doublings 0.
